Surgical pathology report (de-identified scan), TCGA case TCGA-38-4625, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site UNC, specimen TCGA-38-4625-01A (Primary Tumor).

[page 1 of 2]
agnosis:

- : Lung, right upper lobe, lobectomy.
- Poorly differentiated adenocarcinoma, tumor size 5.0 cm in greatest dimension.
- Surgical margins free of tumor.
- No tumor seen in two hilar lymph nodes from lobectomy specimen.

B: Lymph node, station 11, removal.
- No tumor seen in one lymph node (0/1).

C: Lymph node, R4, removal.
- No tumor seen in one lymph node (0/1).

D: Lymph node, station 7, removal.
- No tumor seen in one lymph node (0/1).

E: Pleura, biopsy.
- Fragment of pleura with reactive mesothelial cells, fibrosis and acute and chronic inflammation, no tumor seen.

Comment:

The tumor is markedly pleomorphic and high grade, with rare mucin positive cells. This favors the interpretation of adenocarcinoma.

Clinical History:

Right upper lobe mass.

Gross Description:

Received are five appropriately labeled containers.

Container A is additionally labeled "right upper lobe".

Specimen fixation: formalin

Type of specimen/parts of lung received: received is a right upper lobe, lobectomy

Size of specimen: 14.0 x 9.5 x 2.8 cm

Weight of specimen: 250 g

Other attached structures: none

Tumor location: peripheral

Tumor size and description: 5.0 x 4.2 x 3.6 cm; tumor grossly appears as a circumscribed, white/tan, focally softened, and focally hemorrhagic nodule, which is located under the peripheral pleura Relationship of tumor to bronchus: 3.0 cm from the closest bronchial margin, does not involve the bronchus

Distance of tumor to bronchial margin: see above

Relationship/distance of tumor to pleura: diffusely abutting the pleura, does not appear to be invading into the pleura, however, the pleura over this nodule is red/brown, diffusely hemorrhagic and contains thick, gray/brown adhesions.

Distance of tumor to other surgical margins: The tumor is 3.4 cm from the closest stapled (blue inked) margin.

Presence/absence of satellite tumor nodules: absent

Description of nontumorous lung: The remainder of the specimen has a brown/red, smooth, spongy cut surface with no other grossly identifiable lesions.

- A1 - bronchial and vascular margins, with one hilar lymph node candidate
- A2 - tangential blue inked margin at closest approach to tumor
- A3 - remaining tangential surgical margin
- A4 - tumor with pleura
- A5,A6 - representative tumor
- A7 - representative normal

Container B is additionally labeled "station 11". The specimen consists of a 1.0 x 0.6 x 0.2 cm aggregate of dark brown red tissue which is submitted in toto in block B1.

Container C is additionally labeled "R4". It holds a 0.8 x 0.6 x 0.4 cm fragment of pink/tan tissue which is bisected. C1,

Container D is additionally labeled "station 7". It holds a 1.1 x 0.9 x 0.2 cm aggregate of gray/brown tissue fragment. D1,

[page 2 of 2]
Container E is additionally labeled "pleural biopsy at azygous vein". The specimen consists of a 1.1 x 1.0 x 0.1 cm fragment of red/brown soft tissue. E1, [REDACTED]

Light Microscopy:

Light microscopic examination is performed by Dr.

Container A:

Tumor histologic type (WHO classification): adenocarcinoma

Tumor histologic grade (WHO classification): poorly differentiated

Tumor size (greatest dimension): 5.0 cm

Histologic assessment of surgical margins: surgical margins free of tumor

Pleural involvement: not involved

In situ carcinoma: not identified

Invasion:

angiolymphatic - not identified

perineural - not identified

Lymph nodes (by node group): all lymph nodes are free of tumor

Findings in nontumorous lung: focal post-obstructive changes

Source: NCI Genomic Data Commons file a977d462-7ff7-4e0a-a3c4-1c4d5d5e342e (TCGA-38-4625.EDE2780E-09FD-43AD-A29B-6CA1667D2965.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).